Somatic mutation profile of tumor specimen TARGET-30-PARRLH-01A (aliquot TARGET-30-PARRLH-01A-01D) from TARGET case TARGET-30-PARRLH, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Peripheral nerves and autonomic nervous system of abdomen; Age at diagnosis: 3.6 years (1,299 days).
Specimen TARGET-30-PARRLH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b6a9e01-98a8-4e76-91eb-9381780b5eae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARRLH-10A (Blood Derived Normal), aliquot TARGET-30-PARRLH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c89ed0f-eb20-4338-b514-498e7f1d546d

The open-access MAF lists 20 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 16, Splice Site 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AVPR2 | c.559A>T p.S187C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV61687023; called by muse, mutect2, varscan2
- CACNA1F | c.2281C>A p.L761M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59904974; called by mutect2, varscan2
- CEP43 | c.439-1G>C p.X147_splice | Splice Site (SNP) | VAF 10/18 reads (56%) | catalogued as COSV62760655, COSV62761818; called by mutect2, varscan2
- DCX | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 58/195 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as rs867190240; called by muse, mutect2, varscan2
- FGA | c.1201G>T p.G401W | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57401385; called by mutect2, varscan2
- IFT172 | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1185154683, COSV53139821; called by muse, mutect2, varscan2
- MUC16 | c.23193C>G p.I7731M | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV67495625; called by muse, mutect2, varscan2
- NEDD1 | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 84/302 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV57143922, COSV57146982; called by muse, mutect2, varscan2
- PPM1L | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.834); catalogued as COSV55571298; called by mutect2, varscan2
- S100A14 | c.31-1G>C p.X11_splice | Splice Site (SNP) | VAF 9/26 reads (35%) | catalogued as COSV59885183; called by muse, mutect2, varscan2
- SMAD1 | c.613C>T p.H205Y | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0.071); catalogued as COSV57471921, COSV57473542; called by mutect2, varscan2
- WAS | c.838C>A p.Q280K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV64997763; called by mutect2, varscan2
- AHNAK2 | c.16786G>A p.G5596S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- AXIN2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 45/289 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LRRFIP1 | c.370T>C p.S124P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SBF2 | c.2320C>A p.P774T | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFAT | c.2168A>T p.Q723L | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ZNF667 | c.1267A>T p.M423L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.115); called by muse, mutect2
- GABRQ | c.684G>T p.L228= | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as COSV64784004; called by muse, mutect2, varscan2
- TTN | c.59844C>A p.G19948= (on ENST00000591111; = p.G12524= on NM_003319.4) | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as COSV60363271; called by muse, mutect2, varscan2
